Gene-level copy-number profile of tumor specimen TCGA-A5-A0G2-01A from TCGA case TCGA-A5-A0G2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 57.4 years (20,953 days).
Specimen TCGA-A5-A0G2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.dec5f42a-e6ac-4af4-85b7-9e111eb33ad9.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A5-A0G2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ab51c37a-4edd-4c07-8660-9775d1045550

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,964; copy number 1: 12,248; copy number 2: 37,392; copy number 3: 7,361; copy number 4: 290; copy number 5: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-A5-A0G2-01): tumor purity 0.42, ploidy 1.85, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,038,842–62,078,859, 4 genes: LAMTOR5P1, RN7SL180P, MIR3116-1, MIR3116-2.
- chr4:14,690,710–14,690,832, 1 gene: SNORA63.
- chr4:181,522,666–181,591,969, 2 genes: AC093840.1, AC093840.2.
- chr5:32,174,471–32,312,987, 5 genes: AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P.
- chr5:59,039,761–59,529,251, 3 genes: AC092343.1, AC008833.1, NDUFB4P2.
- chr5:65,625,004–65,666,233, 1 gene (within-gene range 0–1): TRAPPC13.
- chr5:65,665,928–66,082,546, 7 genes (within-gene range 0–1): SGTB, NLN, AC008958.1, AC010359.2, ERBIN, AC010359.1, AC010359.3.
- chr5:131,423,921–131,797,063, 5 genes (within-gene range 0–1): RAPGEF6, AC008695.1, AC008497.1, FNIP1, ACTBP4.
- chr7:91,311,368–91,556,848, 3 genes (within-gene range 0–2): AC079760.2, NIPA2P1, AC079760.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:130,004,528–130,008,453, 2 genes, copy number 5: RNU7-181P, MIR5194.
- chr19:42,821,863–43,269,530, 16 genes, copy number 5: PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8, PSG2, CEACAMP9, AC005392.1, PSG5, PSG4, CEACAMP10, PSG9.

Autosomal genes at a single copy (total copy number 1): 12,245. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
